Somatic mutation profile of tumor specimen C3N-01799-02 (aliquot CPT0089340009) from CPTAC case C3N-01799, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 81.3 years (29,707 days).
Specimen C3N-01799-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3ded7bc-e27d-48c4-8bb0-0f5a8d8bf6ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01799-31 (Blood Derived Normal), aliquot CPT0091320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ae69129-2272-4881-bef8-f362c4b3f91d

The open-access MAF lists 51 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 2, Frame Shift Del 2, 5'UTR 1, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 84/586 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AVIL | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV57680891; called by muse, varscan2
- FUT8 | c.1508A>G p.N503S (on ENST00000360689 / NM_001371534.1; = p.N340S on NM_004480.4) | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1182631569; called by muse, mutect2, varscan2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 24/166 reads (14%) | catalogued as rs755581817; called by mutect2, varscan2
- HSPG2 | c.7935G>C p.Q2645H | Missense Mutation (SNP) | VAF 39/438 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65977412; called by muse, mutect2
- KRBA1 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.508); catalogued as COSV55441135; called by muse, varscan2
- KRBA1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); catalogued as rs1323721653; called by muse, varscan2
- LTBP2 | c.2051C>A p.T684N | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1374074753; called by muse, mutect2
- MED13L | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 71/452 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56120777; called by muse, mutect2, varscan2
- PPP1R9A | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195714; called by muse, mutect2, varscan2
- TLR6 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs556706627, COSV67935165; called by muse, mutect2
- WNT10A | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs915885112; called by muse, mutect2
- ALCAM | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C20orf96 | c.661A>G p.I221V (on ENST00000360321 / NM_153269.3; = p.I220V on NM_080571.1) | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCDC141 | c.2499G>C p.K833N | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CHD4 | c.3665G>A p.G1222E (on ENST00000357008 / NM_001363606.2; = p.G1235E on NM_001273.5) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DRD4 | c.1115G>C p.C372S | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- FANCA | c.1699del p.T567Pfs*38 | Frame Shift Del (DEL) | VAF 65/550 reads (12%) | called by mutect2, pindel, varscan2
- GCOM1 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HES3 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- IL17RD | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- ITGA2B | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 65/684 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.307); called by muse, mutect2
- LRP1 | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 118/394 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV2 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- PLEKHF2 | c.747C>G p.D249E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PRR12 | c.296G>C p.G99A (on ENST00000615927; = p.G920A on NM_020719.3) | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SGIP1 | c.2300-2_2305delinsTTTTTTTT p.X767_splice | Splice Site (ONP) | VAF 6/45 reads (13%) | called by mutect2*, pindel
- SMARCC2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SPIDR | c.550T>G p.Y184D | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPRED2 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TANC2 | c.3576del p.I1192Mfs*28 | Frame Shift Del (DEL) | VAF 27/226 reads (12%) | called by mutect2, pindel, varscan2
- UBR4 | c.10233C>G p.F3411L | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- ZSCAN2 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- C1orf167 | c.1314G>A p.A438= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs962210907; called by muse, mutect2, varscan2
- IQSEC1 | c.951C>A p.P317= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- LCE3D | c.63T>C p.C21= | Silent (SNP) | VAF 76/443 reads (17%) | called by muse, mutect2, varscan2
- MUSK | c.1011C>T p.L337= | Silent (SNP) | VAF 54/474 reads (11%) | called by muse, varscan2
- MYCBP2 | c.10152A>G p.L3384= (on ENST00000357337; = p.L3422= on NM_015057.5) | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- PA2G4 | c.276G>A p.L92= | Silent (SNP) | VAF 30/277 reads (11%) | called by muse, mutect2, varscan2
- PCDHA13 | c.465T>C p.D155= | Silent (SNP) | VAF 32/374 reads (9%) | catalogued as COSV99165490; called by muse, mutect2
- PCLO | c.9570G>T p.V3190= | Silent (SNP) | VAF 45/480 reads (9%) | called by muse, mutect2
- PPP1R3F | c.2095C>T p.L699= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs974423023; called by muse, mutect2
- SLC38A6 | c.750T>A p.A250= | Silent (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- SMARCC2 | c.480C>T p.I160= | Silent (SNP) | VAF 33/218 reads (15%) | called by muse, varscan2
- SMARCC2 | c.430C>T p.L144= | Silent (SNP) | VAF 40/296 reads (14%) | catalogued as COSV57214623; called by muse, varscan2
- SPINT1 | c.60C>G p.V20= | Silent (SNP) | VAF 34/268 reads (13%) | called by muse, mutect2, varscan2
- ZNF843 | c.1002G>A p.P334= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- CIC | c.4328-17G>T | Intron (SNP) | VAF 59/444 reads (13%) | called by muse, mutect2, varscan2
- COL4A1 | c.441+21G>A | Intron (SNP) | VAF 27/400 reads (7%) | called by muse, mutect2
- FUBP1 | c.*25G>C | 3'UTR (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- RCC1 | c.-326A>C | 5'UTR (SNP) | VAF 39/375 reads (10%) | called by muse, mutect2, varscan2
